CGCI case BLGSP-71-23-00442 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d0eab51-3930-48ba-b5fd-ddb2ff100b80

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 40 years; Vital status: Dead.

Diagnoses (1)
1. Primary of the hematopoietic system (histology not recorded by GDC). Age at diagnosis: 40.1 years (14,655 days); Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 16251 [Blood test normal range upper: 480].

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00442-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-23-00442-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00442-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00442-01-Ki67: Tissue microarray coordinates: D1,A3,C5.
  Slide BLGSP-71-23-00442-01-CD20: Tissue microarray coordinates: D1,A3,C5.
  Slide BLGSP-71-23-00442-01-BCL2: Tissue microarray coordinates: D1,A3,C5.
  Slide BLGSP-71-23-00442-01-CD3: Tissue microarray coordinates: D1,A3,C5.
  Slide BLGSP-71-23-00442-01-CD10: Tissue microarray coordinates: D1,A3,C5.
  Slide BLGSP-71-23-00442-01-HE-1: Tissue microarray coordinates: D1,A3,C5.
  Slide BLGSP-71-23-00442-01-BCL6: Tissue microarray coordinates: D1,A3,C5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lost to follow-up: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology: Lymph nodes examined: Yes.
- Tests performed: LDH level: 16251; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
